Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87C, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87C-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

ICD-O:3

Final

Adenocarcinoma, acinar
8140/3

Site: Prostate NOS
C61.9

9/21/21/13

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service:

Accession #: [REDACTED]

Location

Gender: M

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

PROSTATE, EXCISION - ADENOCARCINOMA

LYMPH NODE, BILATERAL PELVIC, EXCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY
(10/10)

SEMINAL VESICLE, BILATERAL, EXCISION - NO HISTOPATHOLOGIC ABNORMALITY

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides(and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out
M.D.***

Intraoperative Consultation:

Two intraoperative non-microscopic consultations were obtained and interpreted
as: "Called to pick up 'FS2,' consisting of a 5 x 3 x 1 cm portion of tissue,
dissected to show a large 3.5 x 1.2 x 1 cm fatty lymph node. Bisected and
frozen as FS2. Rest for permanents," by

"Called to pick up 'prostate," consisting of a 72 gram, 5.5 x 4.5 x 4.5 cm
prostate with attached bilateral seminal vesicles. Inked black. Portion from
each lobe taken for tumor bank. Rest for permanents," by

FS1: Lymph node, right pelvic, excision

- "No metastatic carcinoma," by

FS2: Lymph node, left pelvic, excision

- "No evidence of metastatic carcinoma," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

[page 2 of 4]
Patient Name: [REDACTED]

History:

The patient is a [REDACTED] year old black man with prostate carcinoma [REDACTED]

Operative procedure: Nerve-sparing radical prostatectomy.

Specimen(s) Received:

A: LYMPH NODE, RIGHT PELVIC

B: LYMPH NODE, LEFT PELVIC

C: PROSTATE

Gross Description

The specimens are received in two formalin-filled containers, each labeled "[REDACTED]". The first container is labeled "FS1/X" and contains a white cassette that holds two fragments of tan tissue, the larger fragment measuring 2.5 x 1 x 0.2 cm; the smaller 2.2 x 1 x 0.2 cm. Also in the container are multiple fragments of tan soft tissue measuring 2 x 2 x 0.3 cm. Labeled A1 (FS1); A2 - remaining tissue. Jar 0.

The second container is labeled "FS2XL pelvic LN." It holds a white cassette designated as "FS2." It holds a single fragment of tan tissue measuring 2 x 1.5 x 0.2 cm. Also in the container are multiple fragments of adipose tissue measuring 5 x 4 x 0.3 cm. Labeled B1 (FS2); B2 and B3 - remaining tissue. Jar 0.

The third container is labeled "prostate." It holds a previously inked prostate that weighs 72 grams and measures 5.5 x 4.5 x 4.5 cm. The right seminal vesicle measures 3 x 1.5 x 1.2 cm; the left seminal vesicle measures 2.5 x 1.5 x 1.2 cm.

The right vas deferens measures 3 x 0.6 x 0.5 cm; the left vas deferens measures 1.5 x 0.5 x 0.5 cm. Tissue has been taken from the right as well as the left lobes for tumor bank. The right lobe defect measures 2.2 x 0.3 x 0.5 cm; the left lobe defect measures 2.5 x 0.5 x 0.5 cm. The prostatic urethra is probe-patent with normal seminal vesicles. On sectioning, the seminal vesicles are unremarkable. Labeled: C1 - right and left bladder neck shave margins; C2 and C3 - radial sections of the right apex margin; C4 and C5 - radial sections of the left apex margin; C6 and C7 - right base; C8 and C9 - right apex; C10 and C11 - left base; C12 and C13 - left apex; C14 - right seminal vesicle; C15 - left seminal vesicle. Jar 2.

SYNOPTIC

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 10% (crude visual estimate)

GLEASON'S SCORE

The Gleason's score is 4+3

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left base
left apex

EXTRAPROSTATIC EXTENSION

[page 3 of 4]
Patient Name: [REDACTED]

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

Tumor comes within one cell width of the inked margin in the left apex

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic (0/10)

PRIMARY TUMOR

T2c

REGIONAL LYMPH NODES

NX

DISTANT METASTASIS

MX

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the

as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the [REDACTED] has not been cleared or approved by the U. S. Food and Drug Administration.

File	Yes	No
Case Is Female		

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $4+3=7$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $3+4=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Review

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 357f40cb-e0a7-4292-bc25-07e564d70628 (TCGA-VP-A87C.2E0994EC-7C5F-4721-972D-5D590674D6AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).